CCDI case PBBXCD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a32039da-52c8-4caf-a575-df0d8b50ed27

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.6 years (7,152 days).

Biospecimens (3 samples)
- Sample 0DK3E7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK3EB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DK3EO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
